Gene-level copy-number profile of tumor specimen TCGA-DX-A23R-01A from TCGA case TCGA-DX-A23R, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 56.0 years (20,442 days).
Specimen TCGA-DX-A23R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.480f3e67-5fdd-4f9d-b703-418f94f1de4a.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,931 have no estimate.
https://portal.gdc.cancer.gov/files/72ba85ae-ce4f-4f9b-8b87-4ef1a461774d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 10,261; copy number 2: 38,735; copy number 3: 7,220; copy number 4: 152; copy number 5: 88; copy number 6: 34; copy number 7: 194.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A23R-01A-11D-A26F-01): tumor purity 0.97, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:35,350,305–35,433,283, 8 genes: SLFN11, AC060766.3, AC060766.6, AC060766.4, AC060766.7, AC060766.5, AC060766.1, SLFN12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 316 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:50,268,161–50,422,316, 6 genes, copy number 5 (within-gene range 3–5): AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr12:1,929,202–2,004,535, 2 genes, copy number 7: LINC00940, DCP1B.
- chr12:2,004,666–2,049,463, 3 genes, copy number 7: AC005342.1, CACNA1C-IT1, CACNA1C-IT2.
- chr12:8,548,361–8,783,095, 10 genes, copy number 7 (within-gene range 2–7): AC092746.1, Y_RNA, AC092184.1, AICDA, AC092184.2, HADHAP2, MFAP5, AC092490.2, AC092490.3, RIMKLB.
- chr12:15,882,387–15,903,478, 1 gene, copy number 7: STRAP.
- chr12:33,923,374–33,923,480, 1 gene, copy number 6: RNU6-472P.
- chr12:42,398,550–42,398,651, 1 gene, copy number 7: RNU6-249P.
- chr12:46,384,233–46,407,166, 3 genes, copy number 7: AC025031.1, AC025031.4, AC025031.5.
- chr12:47,593,208–48,106,079, 27 genes, copy number 5 (within-gene range 3–5): AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2.
- chr12:48,231,098–48,284,210, 1 gene, copy number 6 (within-gene range 3–6): AC024257.1.
- chr12:51,590,266–51,923,361, 11 genes, copy number 5–6 (within-gene range 3–6): SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1.
- chr12:54,948,015–55,585,471, 30 genes, copy number 7: TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76, AC122685.1, OR6C2, OR6C68, OR6C64P, OR6C4, OR2AP1.
- chr12:55,654,558–56,044,697, 34 genes, copy number 5–7: PSMB3P1, AC009779.5, METTL7B, ITGA7, AC009779.3, BLOC1S1, RDH5, CD63, AC009779.2, Metazoa_SRP, AC009779.1, GDF11, SARNP, AC023055.1, AC073487.1, ORMDL2, DNAJC14, TMEM198B, MMP19, OLA1P3, GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26.
- chr12:56,923,133–58,395,138, 77 genes, copy number 7 (broad region; genes not listed).
- chr12:59,719,698–59,719,944, 1 gene, copy number 6: AC079905.2.
- chr12:60,092,864–60,269,686, 3 genes, copy number 6: AC080011.1, AC087883.2, AC087883.1.
- chr12:63,271,404–63,272,336, 1 gene, copy number 7: HNRNPA1P69.
- chr12:65,758,020–65,966,291, 2 genes, copy number 7 (within-gene range 3–7): RPSAP52, HMGA2.
- chr12:66,275,940–66,343,643, 3 genes, copy number 6: PDCL3P7, RN7SKP166, HELB.
- chr12:66,563,524–66,569,194, 2 genes, copy number 5: OSBPL9P5, OSBPL9P4.
- chr12:67,571,197–67,978,387, 7 genes, copy number 6: LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1.
- chr12:68,001,394–68,036,853, 2 genes, copy number 6: RPL39P28, HNRNPA1P70.
- chr12:68,610,855–68,793,964, 7 genes, copy number 5 (within-gene range 1–5): RAP1B, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3.
- chr12:69,400,903–70,243,379, 16 genes, copy number 7 (within-gene range 3–7): RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1.
- chr12:71,439,798–71,927,248, 15 genes, copy number 7: LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:74,656,561–74,728,851, 3 genes, copy number 5: AC123904.2, AC123904.1, AC123904.3.
- chr12:75,334,670–75,432,688, 2 genes, copy number 6: GLIPR1L1, GLIPR1L2.
- chr12:76,984,079–77,065,569, 2 genes, copy number 5–7: AC025161.1, E2F7.
- chr12:78,052,181–78,091,737, 1 gene, copy number 7 (within-gene range 3–7): AC073571.1.
- chr12:80,792,520–80,937,925, 3 genes, copy number 6 (within-gene range 1–6): LIN7A, MIR617, AC078886.1.
- chr12:83,151,331–83,661,719, 3 genes, copy number 6–7: RPL6P25, AC090680.1, AC093025.1.
- chr12:84,154,434–84,294,562, 2 genes, copy number 5 (within-gene range 1–5): AC090679.2, AC090679.1.
- chr12:89,947,693–89,949,726, 1 gene, copy number 7: LINC02399.
- chr12:92,702,843–93,641,586, 23 genes, copy number 5–7: PLEKHG7, EEA1, RNU6-1329P, LINC02413, AC138123.1, Y_RNA, AC021646.1, RPL41P5, AC138123.2, NACAP8, LINC02412, AC126172.1, AC124947.2, AC124947.1, NUDT4, UBE2N, Y_RNA, MRPL42, RN7SL737P, AC025260.1, SOCS2-AS1, SOCS2, AC012085.1.
- chr12:93,707,791–93,737,823, 1 gene, copy number 6 (within-gene range 6–7): AC012085.2.
- chr12:94,361,220–94,361,526, 1 gene, copy number 6: RN7SL330P.
- chr16:46,702,282–46,978,983, 8 genes, copy number 7 (within-gene range 2–7): MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3.

Autosomal genes at a single copy (total copy number 1): 10,261. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
